TCGA case TCGA-BG-A0M6 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/002724fa-7051-49fa-9c58-4bcb7eba4ac6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Dead; Days to death: 671 days (1.8 years).

Diagnoses (3)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 73.0 years (26,666 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC2; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 3; Lymph nodes tested: 5.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 100.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 5; Lymph nodes tested: 16.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 45 days; Days to treatment end: 167 days; Number of cycles: 6; Treatment dose: 2,280 mg; Prescribed dose: 450; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 45 days; Days to treatment end: 167 days; Number of cycles: 6; Treatment dose: 1,545 mg; Prescribed dose: 260; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 195 days; Days to treatment end: 227 days; Treatment dose: 4,500 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Implants; Treatment intent type: Adjuvant; Days to treatment start: 231 days; Days to treatment end: 241 days; Treatment dose: 1,800 cGy; Course number: 1; Number of fractions: 3; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Infiltrating duct mixed with other types of carcinoma: ICD-O-3 morphology code: 8523/3; Tissue or organ of origin: Breast, NOS; Laterality: Left; Classification of tumor: Prior primary; AJCC staging edition: 6th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Days to treatment start: -1,426 days (-3.9 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -1,401 days (-3.8 years); Treatment anatomic sites: Locoregional Site.
3. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: Other ill-defined sites; Laterality: Left; Classification of tumor: Prior primary; AJCC staging edition: 6th; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 241 days; Disease response: Tumor Free.
- Days to follow up: 671 days (1.8 years); Disease response: Tumor Free.
- Peritoneal washing results: Positive; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 55 kg; Height: 152 cm; BMI: 23.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BG-A0M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 320 mg.
  Slide TCGA-BG-A0M6-01A-03-TSC: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 20; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BG-A0M6-01A-03-BSC: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 40; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BG-A0M6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BG-A0M6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Serous endometrial adenocarcinoma; Method initial path diagnosis: Tumor resection; Surgical approach at diagnosis: open; Lymph nodes pelvic pos by IHC: 0; Lymph nodes aortic pos by IHC: 0.
- Follow-up form: History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: infiltrating duct with mixed typoes of carcinoma.
- Other malignancy form 1, Drug treatment: Pharmaceutical therapy extent: Locoregional.
- Other malignancy form 1, Drug treatment, Administered drug: Pharmaceutical therapy drug name: Arimidex.
- Other malignancy form 1, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Trunk; Other malignancy histological type: Basal cell carcinoma.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: -1174.
- Other malignancy form 2, Drug treatment, Administered drug: Pharmaceutical therapy drug name: no drug recieved.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 671 days; disease-specific survival: no event (censored), 671 days; disease-free interval: no event (censored), 671 days; progression-free interval: no event (censored), 671 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BG-A0M6-01A-31D-A102-01): tumor purity 0.69, ploidy 3.3, whole-genome doublings 1.
